Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0UV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0UV-01A (Primary Tumor).

[page 1 of 3]
108-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1 10/5/11

Surgical Pathology Report

Patient Name: [REDACTED]
Med Rec No: [REDACTED]
DOB: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]

Client:
Location:
Pt. Phone no

Accession #: [REDACTED]
Taken:
Received:
Reported:

History/Clinical Dx: Endometrial cancer, (grade III)

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Uterus, cervix
- B: Right adnexa
- C: Left adnexa
- D: Left pelvic lymph node
- E: Left periaortic lymph node
- F: Right pelvic lymph node
- G: Right periaortic lymph node
- H: Omentum
- I: Pelvic biopsies
- J: Abdominal wall biopsies

DIAGNOSIS:

A. Uterus, cervix:

ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	TAH-BSO with staging
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 3
Nuclear grade:	3
Tumor size:	6.5 x 6.5 x 3.0 cm
Extent of invasion:	Greater than 50% (13mm of invasion; 20mm myometrial thickness)
Lympho/vascular invasion:	Present
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Other findings:	Adenomyosis
Special studies:	On request
Staging information:	T1c, N1 (Stage IIIC)

B. Right adnexa:

Tube and ovary with no evidence of tumor

Regulatory Statement:
The following statement may be applicable to some of the tests/procedures used in developing the above report: This test was developed and its performance characteristics determined by the laboratory. The following statement may be applicable to some of the tests/procedures used in developing the above report: This test was developed and its performance characteristics determined by the laboratory. The following statement may be applicable to some of the tests/procedures used in developing the above report: This test was developed and its performance characteristics determined by the laboratory. The following statement may be applicable to some of the tests/procedures used in developing the above report: This test was developed and its performance characteristics determined by the laboratory.

[page 2 of 3]
Surgical Pathology Report

- C. Left adnexa: Tube and ovary with no evidence of tumor
- D. Left pelvic lymph nodes: Five lymph nodes negative for metastasis (0/5)
- E. Left periaortic lymph nodes: Five lymph nodes negative for metastasis (0/5)
- F. Right pelvic lymph nodes: METASTASIS TO 1 OF 3 LYMPH NODES (1/3)
- G. Right periaortic lymph nodes: Three lymph nodes negative for metastasis (0/3)
- H. Omentum: No evidence of tumor
- I. Pelvic biopsies: Inflammation with no tumor identified
- J. Abdominal wall biopsies: Inflammation with no tumor identified

Intraoperative Consultation:

- A. Frozen Section Interpretation: Malignant

Gross Description

- A. Received fresh for frozen section labeled "uterus and cervix" is a previously opened uterus with attached cervix weighing 234.0 grams and measuring 10.0 x 8.0 x 8.0 cm in the open state. The cervix measures 3.0 x 3.0 cm; the cervical os is free of any discrete lesion. The serosal surface is tan to pink and smooth. The endometrial cavity is filled with a large fungating, tan-red exophytic friable mass, measuring approximately 6.5 x 6.5 x 3.0 cm. The tumor extends from the fundus to the lower uterine segment; the upper endocervical canal appears free of tumor. On cut section, the tumor grossly appears to be invade more than half of the myometrial thickness (myometrial thickness 2.0 cm, myometrial thickness at the deepest tumor invasion is 0.7 cm). The bulk of the tumor is present on the posterior endometrial wall. The anterior endometrial wall has uninvolved endometrium which measures up to 0.3 cm in thickness. The uninvolved myometrium is tan to pink and has a small leiomyoma, measuring 0.8 x 0.8 x 0.8 cm. Representative sections are submitted.

Description of blocks: 1-anterior and posterior cervix, 2- upper endocervical canal, 3- lower uterine segment, 4- tumor with closest serosal surface, blocks 5-8- tumor, block 9- full thickness endometrium and myometrium, block 10- leiomyoma, block 11- additional tumor, block 12- parametrium.

- B. Received in formalin labeled "[redacted], right adnexa" is a fimbriated segment of ligated fallopian tube and attached ovary. The fallopian tube, approximately 4.0 x 0.3 cm; its cut surface is pinpoint and grossly free of pathologic change. The ovary, 6.0 grams, 3.0 x 1.5 x 1.0 cm. The cut surface reveals mottled, tan-yellow ovarian parenchyma with an occasional corpora albicans. A portion of the ovary has been removed intraoperatively and submitted for cancer research. Representative fallopian tube and ovary, blocks B1-B2.
- C. Received in formalin labeled "[redacted] left adnexa" is a fimbriated segment of ligated fallopian tube and attached ovary. The fallopian tube, approximately 2.5 x 0.3 cm; its cut surface is pinpoint and grossly free of pathologic change. The ovary, 5.0 grams, 2.5 x 1.5 x 1.0 cm. The cut surface reveals mottled, tan-yellow ovarian parenchyma with an occasional corpora albicans. A portion of the ovary has been removed intraoperatively and submitted for cancer research. Representative fallopian tube and ovary, blocks C1-C2.
- D. Received in formalin labeled "[redacted] left pelvic lymph node" is a fragment of tan-yellow fatty soft tissue, 8.0 grams, 3.5 x 3.5 x 2.0 cm. Embedded with the soft tissue, are several soft, tan-pink rubbery lymph nodes, up to 2.0 x 1.5 cm across. The largest lymph nodes are inked and bisected. Entirely submitted, blocks D1-D4.

Key to cassettes:

- D1 - One lymph node, bisected
D2 - One lymph node, bisected
D3 - Two lymph nodes, one bisected
D4 - Remainder of sample

[page 3 of 3]
Surgical Pathology Report

- E. Received in formalin labeled [REDACTED], left periaortic lymph node" is a fragment of tan-yellow fatty soft tissue, 2.0 grams, 3.0 x 1.0 x 0.5 cm. Embedded with the soft tissue, are several soft, tan-pink rubbery lymph nodes, up to 2.3 x 0.6 cm across. The largest lymph node is inked and bisected. Entirely submitted, blocks E1-E3.

Key to cassettes:

- | | | |
|----|---|--------------------------|
| E1 | - | One lymph node, bisected |
| E2 | - | Two lymph nodes |
| E3 | - | Remainder of sample |

- F. Received in formalin labeled [REDACTED] right pelvic lymph node" is a fragment of tan-yellow fatty soft tissue, 4.0 grams, 3.0 x 2.5 x 1.0 cm. Embedded with the soft tissue, is a soft, tan-pink rubbery lymph node, 2.7 x 1.6 cm across. The lymph node is inked and bisected. Entirely submitted, blocks F1-F3.

Key to cassettes:

- | | | |
|-------|---|--------------------------|
| F1-F2 | - | One lymph node, bisected |
| F3 | - | Remainder of sample |

- G. Received in formalin labeled [REDACTED] right periaortic lymph node" is a fragment of tan-yellow fatty soft tissue, 3.0 grams, 4.0 x 1.5 x 0.5 cm. Embedded with the soft tissue, are several soft, tan-pink rubbery lymph nodes, up to 2.0 x 1.5 cm across. The largest lymph nodes are inked and bisected. Entirely submitted, blocks G1-G4.

Key to cassettes:

- | | | |
|----|---|--------------------------|
| G1 | - | One lymph node, bisected |
| G2 | - | One lymph node, bisected |
| G3 | - | One lymph node |
| G4 | - | Remainder of sample |

- H. Received in formalin labeled [REDACTED] omentum" is a portion of tan-yellow fibroadipose tissue, 162.0 grams, 20.0 x 12.5 x 1.5 cm. The cut surface reveals no gross abnormal palpable induration or lymph nodes. Representative sections, blocks H1-H4.
- I. Received in formalin labeled [REDACTED] pelvic biopsies" are several fragments of tan-red soft tissue, 1.0 grams, 1.0 x 0.8 x 0.3 cm in aggregate. Entirely submitted, block I.
- J. Received in formalin labeled [REDACTED] abdominal wall biopsy" are several fragments of tan-yellow soft tissue, 1.0 grams, 1.2 x 0.9 x 0.3 cm in aggregate. Entirely submitted, block J.

Microscopic Description

A-J. The microscopic findings support the above diagnosis.

[REDACTED]

Source: NCI Genomic Data Commons file fecc91c8-484e-47fc-9b51-9f4ed9ce0dae (TCGA-BS-A0UV.9414D0B9-3126-42E9-8189-7C1EC38B2AAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).